Gene-level copy-number profile of tumor specimen TCGA-ZJ-AAX4-01A from TCGA case TCGA-ZJ-AAX4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 85.6 years (31,258 days).
Specimen TCGA-ZJ-AAX4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.02e8ac5d-55af-4a1b-8b00-1f44f14183d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZJ-AAX4-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c2aa3c34-5ea0-41f3-a64a-ee540e22eb19

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 89; copy number 2: 9,203; copy number 3: 12,837; copy number 4: 29,583; copy number 5: 7,687; copy number 6: 46; copy number 7: 5; copy number 8: 36; copy number 9: 334.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZJ-AAX4-01A-11D-A42N-01): tumor purity 0.69, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 334 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:34,787,801–36,004,667, 1 gene, copy number 9 (within-gene range 4–9): RUNX1.
- chr21:35,472,095–46,665,124, 333 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 89. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
